Somatic mutation profile of tumor specimen TCGA-AW-A1PO-01A (aliquot TCGA-AW-A1PO-01A-12D-A159-09) from TCGA case TCGA-AW-A1PO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 66.3 years (24,225 days).
Specimen TCGA-AW-A1PO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49cbb99c-6646-4684-9516-a9346dbdedc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AW-A1PO-10A (Blood Derived Normal), aliquot TCGA-AW-A1PO-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6dbe163-e931-43d3-9ae5-d6b98fb1459e

The open-access MAF lists 80 somatic variants for this specimen: 62 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 16, Frame Shift Del 5, In Frame Del 4, Nonsense Mutation 3, Splice Site 2, RNA 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 15/19 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACRBP | c.474A>C p.T158= | Splice Region (SNP) | VAF 25/79 reads (32%) | catalogued as COSV99975940; called by muse, mutect2, varscan2
- ADGRF5 | c.1142T>C p.M381T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1021428905, COSV99344936; called by muse, mutect2, varscan2
- AIPL1 | c.95G>C p.R32P | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV100005956; called by muse, mutect2, varscan2
- AL121899.2 | c.390C>A p.Y130* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV101198383; called by muse, mutect2, varscan2
- ANKIB1 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as COSV99728377; called by muse, mutect2, varscan2
- BLM | c.2738T>G p.L913R | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100756945; called by muse, mutect2, varscan2
- CACNA1D | c.4339T>G p.F1447V (on ENST00000350061 / NM_001128840.3; = p.F1467V on NM_000720.4) | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99856646; called by muse, mutect2, varscan2
- CASP1 | c.1088C>T p.S363F (on ENST00000436863 / NM_033292.4; = p.S342F on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as rs756686280, COSV52830597; called by muse, mutect2, varscan2
- CDV3 | c.252A>C p.E84D | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV53912048; called by muse, varscan2
- CEP290 | c.3286G>T p.E1096* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100467866; called by muse, mutect2, varscan2
- CLCC1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV100206227; called by muse, mutect2, varscan2
- COPA | c.2335G>C p.D779H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV99614657; called by muse, mutect2, varscan2
- CYP3A7 | c.1403G>C p.C468S | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100312559; called by muse, mutect2, varscan2
- DNAH10 | c.9098A>C p.K3033T (on ENST00000409039; = p.K2972T on NM_207437.3) | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV101291988; called by muse, mutect2, varscan2
- ESYT2 | c.2431A>G p.R811G (on ENST00000613624; = p.R735G on NM_020728.3) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99276118; called by muse, mutect2, varscan2
- EXOC7 | c.91A>T p.S31C | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100134855; called by muse, mutect2, varscan2
- FAT1 | c.3223G>C p.D1075H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV101499055; called by muse, mutect2, varscan2
- GNAQ | c.739C>G p.R247G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54117813, COSV54126381; called by muse, mutect2, varscan2
- HSD17B14 | c.206T>G p.V69G | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs752270398, COSV99612095; called by muse, mutect2, varscan2
- HSPA6 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100553830, COSV100553908; called by muse, mutect2, varscan2
- KCNQ5 | c.2749G>C p.A917P | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV100571329; called by muse, mutect2, varscan2
- KLHL13 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199927214, COSV99451016; called by muse, mutect2, varscan2
- KLHL38 | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100384253; called by muse, mutect2, varscan2
- MME | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1334129894, COSV100852253; called by muse, varscan2
- MUC16 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.489); catalogued as rs564754555, COSV101198194; called by muse, mutect2, varscan2
- MYO1F | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 44/115 reads (38%) | catalogued as COSV100596373; called by muse, mutect2, varscan2
- NCAPG2 | c.3235G>A p.V1079M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.569); catalogued as COSV99316531; called by muse, mutect2, varscan2
- NLRP1 | c.2332A>G p.T778A | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867951807, COSV99333006; called by muse, mutect2, varscan2
- NRXN2 | c.3429G>T p.K1143N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.068); catalogued as rs1489279418, COSV55455074, COSV99632561; called by muse, mutect2, varscan2
- NTF3 | c.141G>C p.K47N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV100451061, COSV58417133; called by muse, mutect2, varscan2
- PSD4 | c.817T>G p.S273A | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99830837; called by muse, mutect2, varscan2
- RBM24 | c.649G>A p.A217T (on ENST00000379052 / NM_001143942.2; = p.A172T on NM_153020.2) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as rs763531759, COSV100552827; called by muse, varscan2
- RCOR2 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56851644; called by muse, mutect2, varscan2
- RPL10 | c.598A>T p.I200F | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99185815; called by muse, mutect2, varscan2
- SAGE1 | c.98G>T p.S33I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.833); catalogued as COSV100186665; called by mutect2, varscan2
- SLC2A1 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100995783; called by muse, mutect2, varscan2
- SNX30 | c.334A>G p.R112G | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV100953746; called by muse, mutect2, varscan2
- SPINK5 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs780631964, COSV56264284; called by muse, mutect2, varscan2
- ST14 | c.1568G>T p.C523F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99598486; called by muse, mutect2, varscan2
- TACR3 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.179); catalogued as COSV100510104; called by muse, mutect2, varscan2
- TARBP1 | c.3140G>C p.W1047S | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99241093; called by muse, mutect2, varscan2
- TMPRSS2 | c.350G>C p.G117A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.342); catalogued as COSV100151170; called by muse, mutect2, varscan2
- TTN | c.90950G>C p.R30317P (on ENST00000591111; = p.R22893P on NM_003319.4) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | PolyPhen possibly damaging (0.855); catalogued as COSV100594944; called by muse, mutect2, varscan2
- VMO1 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs1269286376, COSV99564567; called by muse, mutect2, varscan2
- WDR47 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.355); catalogued as COSV100728236; called by muse, mutect2, varscan2
- WDR86 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100561141; called by muse, mutect2, varscan2
- ZBTB22 | c.1787G>C p.G596A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.075); catalogued as COSV99801489; called by muse, mutect2, varscan2
- ZMAT4 | c.436T>A p.Y146N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99908601; called by muse, mutect2, varscan2
- ZNF182 | c.1518A>T p.R506S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100526897; called by muse, mutect2, varscan2
- ZNF493 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as COSV62751792; called by muse, mutect2, varscan2
- ZNF676 | c.227-2A>T p.X76_splice (on ENST00000650058; = p.X44_splice on NM_001001411.3) | Splice Site (SNP) | VAF 18/37 reads (49%) | catalogued as rs781568256, COSV101236101; called by muse, mutect2, varscan2
- CA14 | c.243_245del p.N82del | In Frame Del (DEL) | VAF 12/35 reads (34%) | called by pindel, varscan2
- EYS | c.336_344del p.G113_V115del | In Frame Del (DEL) | VAF 14/30 reads (47%) | called by mutect2, pindel, varscan2
- FRYL | c.4385_4396del p.P1462_Y1465del | In Frame Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel
- H2AC6 | c.229_233delinsGTC p.T77Vfs*34 | Frame Shift Del (DEL) | VAF 51/121 reads (42%) | called by pindel, varscan2*
- MED12L | c.4556_4565delinsCATTA p.L1519Sfs*11 | Frame Shift Del (DEL) | VAF 26/37 reads (70%) | called by pindel, varscan2*
- MEGF6 | c.1755_1781del p.P586_C594del | In Frame Del (DEL) | VAF 17/26 reads (65%) | called by mutect2, pindel, varscan2
- MEGF8 | c.3744_3761+27del p.X1248_splice (on ENST00000251268 / NM_001271938.2; = p.X1181_splice on NM_001410.3) | Splice Site (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel
- MTHFS | c.203_218del p.I68Nfs*21 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- NELL2 | c.320_327del p.H107Rfs*10 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.1196_1221del p.P399Hfs*4 | Frame Shift Del (DEL) | VAF 14/101 reads (14%) | called by mutect2, pindel
- AKR1E2 | c.573A>T p.L191= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV100033383; called by muse, mutect2, varscan2
- C12orf57 | c.372C>A p.A124= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1555146557, COSV99980651; called by muse, mutect2, varscan2
- COQ6 | c.954C>T p.V318= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs1007858755, COSV99473744; called by muse, mutect2, varscan2
- DHPS | c.906C>T p.Y302= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs542424645, COSV99269510; called by muse, mutect2, varscan2
- DPY19L3 | c.1749C>T p.A583= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs771233222, COSV100639107; called by muse, mutect2, varscan2
- GCFC2 | c.804A>G p.L268= | Silent (SNP) | VAF 42/48 reads (88%) | catalogued as COSV100319368; called by muse, mutect2, varscan2
- ILVBL | c.471G>A p.R157= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99654581; called by muse, mutect2, varscan2
- MTPN | c.234G>A p.E78= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV101262932; called by muse, mutect2, varscan2
- OR5M8 | c.874A>C p.R292= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100510547; called by muse, mutect2, varscan2
- PCDHGA10 | c.1764C>T p.P588= | Silent (SNP) | VAF 71/139 reads (51%) | catalogued as rs773327918, COSV53984590; called by muse, mutect2, varscan2
- PDE1C | c.579C>A p.L193= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV100371075; called by muse, varscan2
- PRKD2 | c.393C>T p.F131= | Silent (SNP) | VAF 55/120 reads (46%) | catalogued as rs1216877513, COSV99354105; called by muse, mutect2, varscan2
- SLC27A1 | c.1302T>C p.D434= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as COSV99392991; called by muse, mutect2, varscan2
- ZFP2 | c.759A>G p.Q253= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100796979; called by muse, mutect2, varscan2
- ZNF791 | c.474A>G p.K158= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100589031, COSV100589110; called by muse, mutect2, varscan2
- ZNF808 | c.1977C>T p.T659= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100707790; called by muse, mutect2, varscan2
- DEPDC5 | c.*651G>A | 3'UTR (SNP) | VAF 19/40 reads (48%) | catalogued as rs1370092843, COSV99834406; called by muse, mutect2, varscan2
- FRMPD2B | n.1273G>A | RNA (SNP) | VAF 42/111 reads (38%) | called by muse, mutect2, varscan2
